HCMI case HCM-CSHL-0514-C50 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast. Index date (day 0 for every day count below): first patient visit.
https://portal.gdc.cancer.gov/cases/d7b49708-3dd6-4837-856a-bce8ceb8e76f

Demographics
Sex at birth: female; Days to birth: -20,075 days (55.0 years before the index date); Year of birth: 1963; Vital status: Alive.

Diagnoses (1)
1. Lobular carcinoma, NOS: ICD-O-3 morphology code: 8520/3; ICD-10 code: C50.4; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; AJCC staging edition: 8th; AJCC clinical stage: Stage IIA; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 22 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 62 days; Days to treatment end: 80 days.
   Recorded as not given: neoadjuvant treatment (type not reported); prevention Hormone Therapy; adjuvant Pharmaceutical Therapy, NOS, for residual disease.

Follow-up (2 entries)
- Days to follow up: 80 days; Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- ERBB2 (IHC): Negative.
- PGR (IHC): Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 97.6 kg; Height: 184 cm; BMI: 28.8.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Breast Cancer.

Biospecimens (2 samples)
- Sample HCM-CSHL-0514-C50-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample HCM-CSHL-0514-C50-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
